Gene-level copy-number profile of tumor specimen TCGA-FR-A8YD-06A from TCGA case TCGA-FR-A8YD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.0 years (21,535 days).
Specimen TCGA-FR-A8YD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.87c98d64-bc40-413d-bd7e-03c2f65d19a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A8YD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/314a5071-f51e-4795-9100-bc33dbf15657

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,534; copy number 2: 40,588; copy number 3: 8,423; copy number 4: 4,856; copy number 5: 3,145; copy number 6: 9; copy number 7: 261.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A8YD-06A-11D-A371-01): tumor purity 0.79, ploidy 2.4, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,415 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:146,996,607–146,996,713, 1 gene, copy number 6: RNU6-505P.
- chr7:70,972–159,233,377, 3,014 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:17,787,649–18,024,561, 1 gene, copy number 6 (within-gene range 3–6): MICAL3.
- chr22:20,129,456–22,215,270, 131 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr22:25,959,074–26,383,597, 7 genes, copy number 6 (within-gene range 2–6): Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1.
- chr22:39,292,988–49,266,080, 261 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,534. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
